Somatic mutation profile of tumor specimen TCGA-AN-A0XN-01A (aliquot TCGA-AN-A0XN-01A-21D-A10G-09) from TCGA case TCGA-AN-A0XN, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 68.5 years (25,029 days).
Specimen TCGA-AN-A0XN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 95e0b2e2-9d91-459c-9ed3-501e24376f2c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AN-A0XN-10A (Blood Derived Normal), aliquot TCGA-AN-A0XN-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37a487e3-25f4-4ab6-bb12-58cb14f6375f

The open-access MAF lists 154 somatic variants for this specimen: 126 protein-altering or splice-affecting, 25 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 25, Nonsense Mutation 7, Frame Shift Del 6, Splice Site 5, In Frame Del 3, Intron 2, Splice Region 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.376-2A>G p.X126_splice | Splice Site (SNP) | VAF 10/27 reads (37%) | hotspot (GDC flag); catalogued as rs786202799, CS114003, COSV52689235, COSV52691326, COSV53121815, COSV53758902; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCC2 | c.4585T>C p.Y1529H | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.778); catalogued as rs759540575, COSV64988766; called by muse, mutect2, varscan2
- ACSM2B | c.13C>T p.R5* | Nonsense Mutation (SNP) | VAF 30/130 reads (23%) | catalogued as rs745852481, COSV61657708; called by muse, mutect2, varscan2
- ACSM6 | c.584G>T p.G195V | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV58980923; called by muse, mutect2, varscan2
- AFF1 | c.1372C>T p.P458S | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.572); catalogued as COSV57124846; called by muse, mutect2, varscan2
- AHI1 | c.1231A>G p.K411E | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV55636905; called by muse, mutect2, varscan2
- ARHGEF28 | c.1883A>G p.N628S | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.396); catalogued as COSV55271464; called by muse, mutect2, varscan2
- ARL8B | c.515T>G p.I172S | Missense Mutation (SNP) | VAF 57/435 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV56580230; called by muse, mutect2, varscan2
- ASTN1 | c.2949G>T p.Q983H | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV62507806; called by muse, mutect2, varscan2
- ATP8B4 | c.1329T>A p.D443E | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.167); catalogued as COSV52725312; called by muse, mutect2, varscan2
- C12orf50 | c.922+1G>C p.X308_splice | Splice Site (SNP) | VAF 42/248 reads (17%) | catalogued as COSV53899264; called by muse, mutect2, varscan2
- C17orf97 | c.361A>T p.I121F | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV64077568; called by muse, mutect2, varscan2
- CCDC7 | c.2245G>T p.E749* | Nonsense Mutation (SNP) | VAF 31/186 reads (17%) | catalogued as COSV56552738; called by muse, mutect2, varscan2
- CCDC73 | c.2762C>T p.A921V | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367851392; called by muse, mutect2, varscan2
- CD5L | c.493A>G p.T165A | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs765921294, COSV63823269; called by muse, mutect2, varscan2
- CDC37L1 | c.164A>G p.Q55R | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.78); catalogued as COSV67866443; called by muse, mutect2, varscan2
- CDH23 | c.9566G>T p.R3189L | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV56492476; called by muse, mutect2, varscan2
- CFAP43 | c.3866G>A p.R1289H | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.562); catalogued as rs770126385, COSV63853058; called by muse, mutect2
- CHGB | c.1687T>C p.F563L | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.571); catalogued as COSV66761905; called by muse, mutect2, varscan2
- CHI3L1 | c.113A>T p.D38V | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.007); catalogued as COSV55140317; called by muse, mutect2, varscan2
- CLDN19 | c.629C>A p.P210Q | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV56419277; called by muse, mutect2, varscan2
- CLN3 | c.826C>G p.Q276E (on ENST00000360019 / NM_001286104.2; = p.Q300E on NM_000086.2) | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.27); catalogued as COSV61107943; called by muse, mutect2, varscan2
- CNTN6 | c.1646C>T p.A549V | Missense Mutation (SNP) | VAF 11/257 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as COSV100612073; called by muse, mutect2
- COBL | c.3109G>C p.V1037L | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99474633; called by muse, mutect2
- COL15A1 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as COSV66649363, COSV66649735; called by muse, mutect2, varscan2
- COL17A1 | c.3027C>A p.S1009R | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as COSV62227792, COSV62229664; called by muse, mutect2, varscan2
- COL4A5 | c.4075C>T p.P1359S | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV60356306; called by muse, mutect2, varscan2
- CSTF3 | c.2072C>T p.S691L | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.112); catalogued as COSV60614839; called by muse, mutect2, varscan2
- DNAH17 | c.4442C>T p.T1481M | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.17); catalogued as rs370414556; called by muse, mutect2
- DNAH2 | c.2192G>A p.R731H | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.932); catalogued as rs151273416; called by muse, mutect2, varscan2
- DNAH2 | c.2615A>G p.D872G | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV66728012; called by muse, mutect2, varscan2
- DNAH5 | c.1687C>G p.Q563E | Missense Mutation (SNP) | VAF 124/265 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.04); catalogued as rs1170897915, COSV54254852; called by muse, mutect2, varscan2
- EFEMP1 | c.371del p.A124Efs*51 | Frame Shift Del (DEL) | VAF 28/102 reads (27%) | catalogued as COSV62618072; called by mutect2, varscan2
- EFEMP1 | c.370G>T p.A124S | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.077); catalogued as COSV62618076; called by mutect2, varscan2
- EFHC1 | c.325A>G p.M109V | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs772750016, COSV64137944; called by muse, mutect2, varscan2
- EGFLAM | c.2072C>A p.T691N | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.521); catalogued as COSV59319093; called by muse, mutect2, varscan2
- ELOVL3 | c.777C>G p.I259M | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV100892744, COSV64175068; called by muse, mutect2, varscan2
- ERMAP | c.325G>A p.V109I | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV60276224; called by muse, mutect2, varscan2
- EYA2 | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs202115929; called by muse, mutect2, varscan2
- FAM155B | c.762C>A p.D254E | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52937989; called by muse, mutect2, varscan2
- FAM161A | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV56768973; called by muse, mutect2, varscan2
- FAM184A | c.3036G>T p.E1012D | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100138471; called by muse, mutect2
- FAM217A | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 43/274 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as rs1211163854, COSV51162786; called by muse, mutect2, varscan2
- FBXO34 | c.1987G>C p.G663R | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58257375; called by muse, mutect2, varscan2
- FCRLB | c.1109A>T p.D370V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.07); catalogued as COSV61059934; called by muse, mutect2
- FN1 | c.331A>G p.T111A | Missense Mutation (SNP) | VAF 8/161 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100118561; called by muse, mutect2
- GLYR1 | c.1483A>C p.K495Q | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.019); catalogued as COSV100424636; called by muse, mutect2
- GRK3 | c.1231G>A p.V411M | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs1316665820, COSV60795391; called by muse, mutect2, varscan2
- GRM8 | c.2630C>T p.P877L | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV100286925; called by muse, mutect2
- HAUS5 | c.174G>C p.K58N | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV52546739, COSV52550081; called by muse, mutect2, varscan2
- HELZ | c.4840A>C p.S1614R | Missense Mutation (SNP) | VAF 40/243 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.296); catalogued as COSV62381203; called by muse, mutect2, varscan2
- HEPHL1 | c.3104T>C p.I1035T | Missense Mutation (SNP) | VAF 8/220 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as rs1049212969, COSV100244608; called by muse, mutect2
- HK2 | c.850G>T p.G284C | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV99309734; called by muse, mutect2
- HSDL2 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 47/356 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as COSV52717547; called by muse, mutect2, varscan2
- ICE1 | c.4411C>T p.P1471S | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as rs975032068; called by muse, mutect2
- IGSF10 | c.7675G>C p.E2559Q | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.151); catalogued as COSV56399371; called by muse, mutect2, varscan2
- IL22 | c.8C>A p.A3D | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.284); catalogued as COSV60160864; called by muse, mutect2, varscan2
- IQGAP1 | c.4144C>T p.R1382* | Nonsense Mutation (SNP) | VAF 5/68 reads (7%) | catalogued as COSV99185491; called by muse, mutect2
- ITGB1 | c.2050C>G p.Q684E | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV56487184; called by muse, mutect2, varscan2
- ITGB4 | c.2522C>A p.A841D | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1442197236, COSV99565061; called by muse, mutect2
- KDR | c.805C>T p.H269Y | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.194); catalogued as COSV55777354; called by muse, mutect2, varscan2
- KRTAP6-1 | c.185G>T p.G62V | Missense Mutation (SNP) | VAF 32/120 reads (27%) | PolyPhen possibly damaging (0.844); catalogued as COSV58169017; called by muse, mutect2, varscan2
- LENG1 | c.530G>A p.R177H | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs377766733, COSV55366816; called by muse, mutect2, varscan2
- LRP2 | c.9182C>T p.S3061F | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99790813; called by muse, mutect2
- LRRC29 | c.587T>G p.V196G | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.394); catalogued as COSV58528497; called by muse, mutect2, varscan2
- LRRC74A | c.859G>A p.G287R | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV53612640; called by muse, mutect2, varscan2
- MACF1 | c.18401G>A p.C6134Y (on ENST00000372915; = p.C4179Y on NM_012090.5) | Missense Mutation (SNP) | VAF 45/248 reads (18%) | catalogued as COSV57146308; called by muse, mutect2, varscan2
- MARK1 | c.723G>T p.W241C | Missense Mutation (SNP) | VAF 26/347 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65072206; called by muse, mutect2
- MYH10 | c.4303G>A p.D1435N | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as rs1270107270, COSV52612412; called by muse, mutect2, varscan2
- MYL12B | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52899171, COSV52899334; called by muse, mutect2, varscan2
- NEK10 | c.57A>C p.Q19H | Missense Mutation (SNP) | VAF 125/400 reads (31%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); catalogued as COSV58290067; called by muse, mutect2, varscan2
- NET1 | c.199A>G p.R67G | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV100742404; called by muse, mutect2
- NFATC3 | c.301G>C p.G101R | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV60480399; called by muse, mutect2, varscan2
- NRDC | c.210G>C p.Q70H | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.276); catalogued as COSV61409335; called by muse, mutect2, varscan2
- NRDE2 | c.1090G>T p.E364* | Nonsense Mutation (SNP) | VAF 44/112 reads (39%) | catalogued as COSV100583725; called by muse, mutect2
- NRDE2 | c.1088T>C p.L363P | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100583728; called by muse, mutect2
- NRF1 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.014); catalogued as rs1176246998, COSV56217179; called by muse, mutect2, varscan2
- ODF2 | c.1372C>A p.L458I (on ENST00000434106 / NM_153433.2; = p.L434I on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); catalogued as COSV63549119; called by muse, mutect2, varscan2
- OR2AE1 | c.551T>G p.V184G | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV60391276; called by muse, mutect2, varscan2
- OR2M2 | c.572A>G p.D191G | Missense Mutation (SNP) | VAF 62/516 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV62899500; called by muse, mutect2, varscan2
- OR51F2 | c.779T>A p.L260* | Nonsense Mutation (SNP) | VAF 10/148 reads (7%) | catalogued as COSV100438201; called by muse, mutect2
- OR7D4 | c.586A>T p.N196Y | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as COSV58072963; called by muse, mutect2, varscan2
- PAK2 | c.103C>G p.H35D | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV59085935; called by muse, mutect2, varscan2
- PGBD4 | c.536C>A p.T179K | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.549); catalogued as COSV56629368; called by muse, mutect2, varscan2
- PKHD1L1 | c.3020T>C p.I1007T | Missense Mutation (SNP) | VAF 46/278 reads (17%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs917618034, COSV65754309; called by muse, mutect2, varscan2
- PLCG1 | c.2774A>G p.K925R | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.601); catalogued as rs1324516631, COSV99719414; called by muse, mutect2, varscan2
- PLEKHG1 | c.898G>C p.A300P | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100651983, COSV62047220; called by muse, mutect2
- PLOD2 | c.160C>T p.R54* | Nonsense Mutation (SNP) | VAF 50/300 reads (17%) | catalogued as rs780902890, COSV51466917, COSV51469596; called by muse, mutect2, varscan2
- PTGDR | c.532T>G p.C178G | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60095245; called by muse, mutect2, varscan2
- RANGAP1 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV62363547; called by muse, mutect2, varscan2
- RBBP6 | c.2257T>A p.Y753N | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV100155145; called by muse, mutect2, varscan2
- RELN | c.4588+2T>G p.X1530_splice | Splice Site (SNP) | VAF 27/207 reads (13%) | catalogued as COSV100635182; called by muse, mutect2, varscan2
- RETREG1 | c.592C>G p.L198V (on ENST00000306320 / NM_001034850.2; = p.L57V on NM_019000.4) | Missense Mutation (SNP) | VAF 18/219 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100105166; called by muse, mutect2
- RXFP1 | c.2214C>G p.F738L | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs370806249; called by muse, mutect2, varscan2
- SEMA6D | c.965G>A p.S322N | Missense Mutation (SNP) | VAF 5/124 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100317830; called by muse, mutect2
- SEMG2 | c.871T>C p.S291P | Missense Mutation (SNP) | VAF 26/163 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65648029; called by muse, mutect2, varscan2
- SLC26A3 | c.1388G>T p.R463L | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); catalogued as COSV100385375, COSV60640988; called by muse, mutect2
- SLC38A7 | c.881C>A p.T294K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54705005; called by muse, mutect2, varscan2
- SMG7 | c.2742G>A p.E914= | Splice Region (SNP) | VAF 9/89 reads (10%) | catalogued as COSV100750649; called by muse, mutect2
- STAMBPL1 | c.421-1G>T p.X141_splice | Splice Site (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100904937, COSV64222900; called by muse, mutect2, varscan2
- STOX1 | c.2093G>T p.G698V | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV53818304; called by muse, mutect2, varscan2
- SYNE1 | c.6010G>A p.E2004K (on ENST00000367255 / NM_182961.4; = p.E2011K on NM_033071.3) | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); catalogued as rs748641153, COSV55115008; called by muse, mutect2, varscan2
- TAAR6 | c.391T>C p.Y131H | Missense Mutation (SNP) | VAF 12/185 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.739); catalogued as COSV51583889; called by muse, mutect2
- TAF1 | c.2267T>G p.L756* (on ENST00000373790 / NM_138923.4; = p.L777* on NM_004606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 65/272 reads (24%) | catalogued as COSV52126586; called by muse, mutect2, varscan2
- TGS1 | c.644A>T p.Q215L | Missense Mutation (SNP) | VAF 41/318 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV52703512; called by muse, mutect2, varscan2
- TMEM82 | c.294G>C p.E98D | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV53818672; called by muse, mutect2, varscan2
- TTC13 | c.1991A>C p.N664T | Missense Mutation (SNP) | VAF 28/282 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV100793071; called by muse, mutect2, varscan2
- TTC21A | c.1022G>C p.G341A | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.171); catalogued as COSV100087816; called by muse, mutect2, varscan2
- TTLL1 | c.200A>G p.N67S | Missense Mutation (SNP) | VAF 44/240 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56740927; called by muse, mutect2, varscan2
- UBQLN4 | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs757542069, COSV64145280; called by muse, mutect2, varscan2
- USP12 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 77/147 reads (52%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.983); catalogued as rs760502670, COSV56655531; called by muse, mutect2, varscan2
- USP29 | c.2389A>C p.I797L | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.437); catalogued as COSV54145032; called by muse, mutect2, varscan2
- ZNF131 | c.1255C>A p.P419T (on ENST00000509156 / NM_001330707.2; = p.P385T on NM_003432.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61004673; called by muse, mutect2, varscan2
- ZNF334 | c.1483G>T p.G495C | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV61620415; called by muse, mutect2, varscan2
- ZSWIM8 | c.3345G>C p.L1115F (on ENST00000605216 / NM_001242487.2; = p.L1120F on NM_015037.3) | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.994); catalogued as COSV55218357; called by muse, mutect2, varscan2
- AFDN | c.3376_3390del p.S1126_E1130del | In Frame Del (DEL) | VAF 19/124 reads (15%) | called by mutect2, pindel, varscan2
- ASXL3 | c.5116_5122del p.Q1706* | Frame Shift Del (DEL) | VAF 21/83 reads (25%) | called by mutect2, pindel, varscan2
- CASP3 | c.768_799del p.K259Hfs*19 | Frame Shift Del (DEL) | VAF 39/321 reads (12%) | called by mutect2, pindel
- CDRT1 | c.2080_2085del p.T694_A695del | In Frame Del (DEL) | VAF 11/64 reads (17%) | called by mutect2, varscan2
- LIN37 | c.237_240delinsAGAA p.M80E | Missense Mutation (ONP) | VAF 5/60 reads (8%) | called by pindel, varscan2*
- LIN9 | c.1583_1589del p.N528Ifs*2 (on ENST00000366808 / NM_001270410.2; = p.N473Ifs*2 on NM_173083.3 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 40/338 reads (12%) | called by mutect2, pindel, varscan2
- LRCH3 | c.805_812del p.F269Pfs*7 | Frame Shift Del (DEL) | VAF 81/408 reads (20%) | called by mutect2, pindel, varscan2
- MRPL47 | c.502_533+6del p.X168_splice | Splice Site (DEL) | VAF 38/188 reads (20%) | called by mutect2, pindel
- SEPTIN5 | c.113_124del p.S38_G42delinsC | In Frame Del (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- SLC2A12 | c.174_184del p.G59Wfs*16 | Frame Shift Del (DEL) | VAF 5/44 reads (11%) | called by mutect2, pindel
- USP9X | c.3882dup p.C1295Mfs*13 | Frame Shift Ins (INS) | VAF 102/242 reads (42%) | called by mutect2, pindel, varscan2
- ANKRD27 | c.2790A>G p.L930= | Silent (SNP) | VAF 28/114 reads (25%) | catalogued as COSV60136448; called by muse, mutect2, varscan2
- ARHGAP35 | c.213C>T p.D71= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV68336011; called by muse, mutect2, varscan2
- ARMC12 | c.57C>T p.V19= | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV55361901; called by muse, mutect2, varscan2
- CDH17 | c.273T>C p.T91= | Silent (SNP) | VAF 34/326 reads (10%) | catalogued as COSV99218221; called by muse, mutect2
- DAND5 | c.72T>C p.P24= | Silent (SNP) | VAF 6/66 reads (9%) | catalogued as COSV100397344; called by muse, mutect2
- DNAH5 | c.4074C>T p.G1358= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as COSV54254842; called by muse, mutect2, varscan2
- DOCK3 | c.3885G>T p.R1295= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV56551966; called by muse, mutect2, varscan2
- EMC1 | c.2856G>A p.Q952= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs1432674099, COSV64346733; called by muse, mutect2, varscan2
- FLNB | c.4932G>C p.G1644= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV55875733, COSV55897214; called by muse, mutect2, varscan2
- GCC2 | c.2535A>G p.K845= | Silent (SNP) | VAF 10/110 reads (9%) | catalogued as COSV100565697; called by muse, mutect2
- ITLN1 | c.666T>C p.Y222= | Silent (SNP) | VAF 22/172 reads (13%) | catalogued as rs1465311100, COSV58277079; called by muse, mutect2, varscan2
- IVL | c.1068G>T p.L356= | Silent (SNP) | VAF 10/80 reads (13%) | catalogued as COSV64217331; called by muse, mutect2, varscan2
- KIR2DL3 | c.567T>C p.P189= | Silent (SNP) | VAF 57/408 reads (14%) | called by muse, varscan2
- LIMA1 | c.1509C>A p.V503= | Silent (SNP) | VAF 34/161 reads (21%) | catalogued as COSV57967079, COSV57968882; called by muse, mutect2, varscan2
- LRRC49 | c.654T>C p.L218= | Silent (SNP) | VAF 69/258 reads (27%) | catalogued as COSV53016069; called by muse, mutect2, varscan2
- MMP9 | c.741C>T p.D247= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs200792951, COSV63434540; called by muse, mutect2, varscan2
- MYH9 | c.3879C>T p.D1293= | Silent (SNP) | VAF 10/47 reads (21%) | catalogued as COSV53393884; called by muse, mutect2, varscan2
- PEX14 | c.330C>T p.G110= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs772527603, COSV63063862; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIK3C2G | c.30T>C p.N10= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as COSV56836096; called by muse, mutect2, varscan2
- PKD1L1 | c.4581T>C p.A1527= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as rs770522664, COSV56979401; called by muse, mutect2, varscan2
- PLEKHG2 | c.2430A>T p.S810= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV99218365; called by muse, mutect2, varscan2
- RUNX1T1 | c.1536C>T p.S512= (on ENST00000265814 / NM_001198628.1; = p.S485= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/105 reads (15%) | catalogued as rs1427650041, COSV104380162, COSV56164395; called by muse, mutect2, varscan2
- SLC6A19 | c.1218C>T p.A406= | Silent (SNP) | VAF 46/367 reads (13%) | catalogued as rs781037685, COSV58674881; called by muse, mutect2, varscan2
- SPEN | c.2397G>C p.P799= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV101005212, COSV65367862; called by muse, mutect2, varscan2
- ZFP82 | c.1554T>C p.H518= | Silent (SNP) | VAF 29/147 reads (20%) | catalogued as COSV67566932; called by muse, mutect2, varscan2
- AL049634.2 | c.431-5598C>A | Intron (SNP) | VAF 34/184 reads (18%) | catalogued as COSV67547306; called by muse, mutect2, varscan2
- STAG3L2 | n.743G>A | RNA (SNP) | VAF 32/141 reads (23%) | called by muse, mutect2, varscan2
- VSTM4 | c.457+3808_457+3813del | Intron (DEL) | VAF 17/118 reads (14%) | called by mutect2, pindel, varscan2
